CCDI case PBCLRG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Other and unspecified parts of mouth.
https://portal.gdc.cancer.gov/cases/5fe99044-9046-4beb-977a-f294cd6441a6

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Spindle cell rhabdomyosarcoma: ICD-O-3 morphology code: 8912/3; Tissue or organ of origin: Mandible; Age at diagnosis: 7.4 years (2,696 days).

Biospecimens (3 samples)
- Sample 0DVCDQ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVCFE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVCFP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
